Gene-level copy-number profile of tumor specimen ALCH-B02Q-TTP1-A from ALCHEMIST case ALCH-B02Q, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 52.0 years (18,984 days).
Specimen ALCH-B02Q-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 74ab387c-eccc-48ce-9dab-322ccd350c9c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B02Q-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,707 have no estimate.
https://portal.gdc.cancer.gov/files/1ba6031d-94a9-4412-90d8-b5f57b6173d1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 518; copy number 1: 6,857; copy number 2: 47,508; copy number 3: 3,068; copy number 4: 734; copy number 5: 44; copy number 6: 121; copy number 7: 37; copy number 8: 28; copy number 12: 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:223,976,146–223,976,249, 1 gene: RNU6-1319P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 231 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:156,324,437–160,877,850, 63 genes, copy number 5–12 (broad region; genes not listed).
- chr2:161,096,231–169,824,931, 102 genes, copy number 6 (broad region; genes not listed).
- chr2:170,640,374–171,485,052, 17 genes, copy number 6 (within-gene range 2–6): AC007277.1, AC007277.2, AC007405.1, LINC01124, SP5, EIF2S2P4, AC007405.3, Y_RNA, ERICH2, GAD1, AC007405.2, AC007405.4, GORASP2, TLK1, METTL8, RPS26P20, DCAF17.
- chr7:29,514,224–30,634,033, 37 genes, copy number 5 (within-gene range 2–5): AC007255.1, GTF3C6P3, PRR15, ZNRF2P2, TMSB4XP3, DPY19L2P3, MIR550A3, WIPF3, AC004912.1, SCRN1, FKBP14-AS1, FKBP14, PLEKHA8, AC007285.1, AC007036.4, AC007036.5, MTURN, AC007036.2, AC007036.3, RPS27P16, AC007036.1, ZNRF2, MIR550A1, MIR550B1, AC006978.2, AC006978.1, LINC01176, NOD1, AC006027.1, GGCT, AC005154.5, GARS1-DT, AC005154.2, AC005154.4, AC005154.1, AC005154.3, GARS1.
- chr8:57,855,500–57,984,126, 1 gene, copy number 8 (within-gene range 4–8): LINC01602.
- chr8:57,994,509–58,272,450, 6 genes, copy number 8: FAM110B, AC104350.1, AC027698.1, RPL26P26, AC092819.1, AC092819.2.
- chr15:21,980,277–21,981,245, 1 gene, copy number 5: OR11J6P.
- chr20:20,363,691–20,712,644, 4 genes, copy number 5: AL161658.1, INSM1, RALGAPA2, EIF4E2P1.

Autosomal genes at a single copy (total copy number 1): 4,525. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
